Surgical pathology report (de-identified scan), TCGA case TCGA-B2-5636, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B2-5636-01A (Primary Tumor).

SPECIMEN

Right kidney

CLINICAL NOTES

--

GROSS DESCRIPTION

The specimen is received unfixed labeled "right kidney" and consists of a kidney and surrounding fat measuring 25 x 13 x 7 cm. Also received are additional pieces of yellow soft tissue measuring 11.5 x 11 x 3 cm. in aggregate. On cut section there is a red well-circumscribed tumor in the central portion of the kidney at the junction of the renal parenchyma and the renal sinus that measures 3 cm. in greatest cross-sectional dimension. A portion of the specimen is taken for research purposes. Sections after fixation. RS-6. Hilar margins in #1.

MICROSCOPIC DESCRIPTION

Tumor type: Clear cell type renal cell carcinoma
grade: 2 (out of 4; Fuhrman et al. AJSP 6:655,
size: 3 cm
Renal capsule: Negative for malignancy
Renal sinus: Negative for malignancy
Vascular invasion: Absent
Hilar margins: Negative for malignancy
Kidney away from tumor: Occasional sclerotic glomeruli
Patchy mild chronic inflammation
pTNM Stage: T1a

4

DIAGNOSIS

Kidney, right, resection: Clear cell renal cell carcinoma

Source: NCI Genomic Data Commons file 89773419-62b7-4f6c-a74d-cd0dfc0ecc5a (TCGA-B2-5636.16F12096-8C16-4386-AF76-CC3CB2C2D4E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).